Somatic mutation profile of tumor specimen C3L-02646-01 (aliquot CPT0202530007) from CPTAC case C3L-02646, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,321 days).
Specimen C3L-02646-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec33155a-bfa5-438e-8f13-67c1dd6e4252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02646-31 (Blood Derived Normal), aliquot CPT0202660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ed67329-8a7b-4d0b-b4f8-11fd0875da31

The open-access MAF lists 387 somatic variants for this specimen: 256 protein-altering or splice-affecting, 91 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 91, Intron 19, Nonsense Mutation 18, RNA 9, Splice Site 5, 5'UTR 5, 3'UTR 4, Frame Shift Del 4, 5'Flank 3, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 58/341 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934875, CM942116, CM983475, COSV52661607, COSV52839281, COSV53396164; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.2792T>C p.V931A | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs573904763; called by muse, mutect2, varscan2
- ACSS3 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953889155; called by muse, mutect2, varscan2
- ADAMTS12 | c.3890G>C p.G1297A | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); catalogued as COSV61278594; called by muse, mutect2, varscan2
- ADAMTS16 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199521777; called by muse, mutect2, varscan2
- AGBL3 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51950070; called by muse, mutect2
- AKAP12 | c.4902G>C p.M1634I | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1287912598; called by muse, mutect2, varscan2
- APCS | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV54819063; called by muse, mutect2
- ARHGAP28 | c.1115G>A p.G372E (on ENST00000383472 / NM_001366230.1; = p.G213E on NM_001010000.3) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV51636940, COSV51639263; called by muse, mutect2, varscan2
- ATP10B | c.123C>G p.N41K | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.05); catalogued as COSV58778577; called by muse, mutect2, varscan2
- ATP2B3 | c.3284G>T p.R1095L | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs782067205; called by muse, mutect2, varscan2
- C1orf127 | c.384C>A p.Y128* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | catalogued as rs776678177; called by muse, mutect2, varscan2
- C3orf56 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101228976; called by muse, mutect2, varscan2
- C8orf34 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV61370910; called by muse, mutect2, varscan2
- CASP8 | c.622A>G p.I208V (on ENST00000432109 / NM_033355.3; = p.I225V on NM_001228.4) | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51854755; called by muse, mutect2, varscan2
- CDH8 | c.2228C>G p.S743C | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54892269, COSV54907000; called by muse, mutect2
- CEMIP2 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs751260196, COSV65486661; called by muse, mutect2, varscan2
- CEP63 | c.1550A>G p.Q517R | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.396); catalogued as rs758679746; called by muse, mutect2, varscan2
- CHD8 | c.1478G>T p.R493L (on ENST00000646647 / NM_001170629.2; = p.R214L on NM_020920.4) | Missense Mutation (SNP) | VAF 78/439 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.316); catalogued as COSV67871608; called by muse, mutect2, varscan2
- CLCN2 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 78/536 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV55601093, COSV55601563; called by muse, mutect2, varscan2
- CNGB1 | c.2294G>T p.R765L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761839551; called by muse, mutect2, varscan2
- COL6A3 | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs374960915; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DLGAP1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV59839762; called by muse, mutect2
- DNAH3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.212); catalogued as rs766426438; called by muse, mutect2, varscan2
- EFCAB5 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.071); catalogued as COSV57928353; called by muse, mutect2
- EIF4G3 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 25/149 reads (17%) | catalogued as COSV51679857; called by muse, mutect2, varscan2
- ELOVL2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867506828, COSV61155340; called by muse, mutect2
- FAM117B | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1228985904, COSV57417036; called by muse, mutect2, varscan2
- FAT3 | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as COSV53094893, COSV99971876; called by muse, mutect2, varscan2
- FMO3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs200985454, COSV63006775; called by muse, mutect2, varscan2
- FPR1 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV59053233; called by muse, mutect2, varscan2
- GLIPR1L2 | c.549A>G p.I183M | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.477); catalogued as COSV104412370; called by muse, mutect2, varscan2
- GRID2 | c.452A>T p.Y151F | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.682); catalogued as rs199728067; called by muse, mutect2
- GUCY1A2 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 27/160 reads (17%) | catalogued as COSV56483875; called by muse, mutect2, varscan2
- IFT80 | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1302753011; called by muse, mutect2, varscan2
- IL5RA | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV56523835; called by muse, mutect2, varscan2
- KCNJ3 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535098; called by muse, mutect2
- KCNMA1 | c.3790A>T p.M1264L | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.379); catalogued as rs1369279635; called by muse, mutect2, varscan2
- KIAA2026 | c.3517A>G p.I1173V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs777952562; called by muse, mutect2
- LRP1B | c.2440G>A p.G814R | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.134); catalogued as rs760474334; called by muse, mutect2
- MAGEC3 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53575741; called by muse, mutect2, varscan2
- MALRD1 | c.3152C>T p.T1051I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1392645443; called by muse, mutect2, varscan2
- MAP2K3 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 30/895 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs953801481, COSV57569276; called by muse, mutect2
- MINAR1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1012047271, COSV59587347; called by muse, mutect2
- MINK1 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1314375910; called by muse, mutect2
- MROH2B | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV101270533; called by muse, mutect2, varscan2
- MROH9 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV63013137; called by muse, mutect2
- MYO18B | c.4873G>C p.G1625R | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.754); catalogued as rs867416594; called by muse, mutect2, varscan2
- MYOG | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs919519974; called by muse, mutect2, varscan2
- NHSL2 | c.1384del p.L462Yfs*6 (on ENST00000510661; = p.L828Yfs*6 on NM_001013627.2) | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | catalogued as COSV101029940; called by mutect2, pindel, varscan2
- NR1H4 | c.403G>A p.E135K (on ENST00000551379 / NM_001206993.2; = p.E125K on NM_005123.4) | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867947555, COSV51855560, COSV51855950; called by muse, mutect2
- NR2F2 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1165232524; called by muse, mutect2
- NRARP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV63082886, COSV63083075; called by muse, mutect2
- OR13C3 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1031639007, COSV66165873; called by muse, mutect2, varscan2
- OR8H1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100477167; called by muse, mutect2, varscan2
- ORM2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs1364362057; called by muse, mutect2, varscan2
- PCDH15 | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57269542, COSV57272409; called by muse, mutect2, varscan2
- PCDHB4 | c.1777G>C p.G593R | Missense Mutation (SNP) | VAF 124/799 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.015); catalogued as COSV52019372; called by muse, mutect2, varscan2
- PCOLCE2 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.075); catalogued as rs527346018; called by muse, mutect2, varscan2
- PDE1C | c.1395G>C p.Q465H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58513464, COSV58525821; called by muse, mutect2, varscan2
- PELP1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1266015714, COSV52588343; called by muse, mutect2, varscan2
- PFAS | c.3206G>T p.R1069L | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58979334; called by muse, mutect2, varscan2
- PFKFB3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 13/129 reads (10%) | PolyPhen probably damaging (0.998); catalogued as rs919446085; called by muse, mutect2
- PLCG2 | c.1766G>T p.R589L | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63867788; called by muse, mutect2, varscan2
- PPP2R1A | c.1471G>T p.G491* | Nonsense Mutation (SNP) | VAF 36/296 reads (12%) | catalogued as COSV59044445; called by muse, mutect2, varscan2
- PRDM9 | c.1145-1G>C p.X382_splice | Splice Site (SNP) | VAF 42/328 reads (13%) | catalogued as COSV57002675; called by muse, varscan2
- PRPF3 | c.1526+7G>T | Splice Region (SNP) | VAF 35/171 reads (20%) | catalogued as COSV100254922; called by muse, mutect2, varscan2
- RAPGEF3 | c.679C>T p.Q227* (on ENST00000389212; = p.Q185* on NM_006105.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/170 reads (7%) | catalogued as rs1322360947; called by muse, mutect2
- RBM45 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs754843296; called by muse, mutect2, varscan2
- RINL | c.937C>A p.L313I (on ENST00000591812 / NM_001195833.2; = p.L199I on NM_198445.4) | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61574737; called by muse, mutect2, varscan2
- RMDN3 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV53025696; called by muse, mutect2, varscan2
- ROCK2 | c.2850C>G p.I950M | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV59957001; called by muse, mutect2
- SCG2 | c.505A>G p.M169V | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as rs773827385, COSV59539896; called by muse, mutect2, varscan2
- SLC28A1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 122/507 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141441409; called by muse, mutect2, varscan2
- SMAD6 | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs376970006; called by muse, mutect2, varscan2
- SPOCK1 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 13/140 reads (9%) | catalogued as COSV56457823; called by muse, mutect2
- TCEAL5 | c.532C>G p.P178A | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV65503448; called by muse, mutect2, varscan2
- TNN | c.888C>A p.Y296* | Nonsense Mutation (SNP) | VAF 60/395 reads (15%) | catalogued as COSV53432860; called by muse, mutect2, varscan2
- USH2A | c.6655G>T p.G2219* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | catalogued as COSV56358307; called by muse, mutect2, varscan2
- ZFYVE26 | c.5560G>A p.E1854K | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1423312030; called by muse, mutect2
- ZNF197 | c.2495del p.N832Tfs*3 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as rs1478866648; called by mutect2, pindel, varscan2
- ZNF517 | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV63465458; called by muse, mutect2, varscan2
- ZNF528 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs371372775; called by muse, mutect2
- ZNF530 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 21/315 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.585); catalogued as COSV100252789; called by muse, mutect2
- AC008397.2 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2
- ADAM11 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM22 | c.2291G>C p.R764P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2
- ANKRD30B | c.3489G>C p.K1163N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by mutect2, varscan2
- ARHGAP4 | c.420dup p.R141Afs*16 | Frame Shift Ins (INS) | VAF 54/190 reads (28%) | called by mutect2, pindel, varscan2
- ASCC3 | c.2845C>A p.H949N | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- BPTF | c.6329T>G p.F2110C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C18orf63 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, varscan2
- C18orf63 | c.924G>C p.K308N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- C2CD4A | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CACNA1I | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 56/462 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CACNG8 | c.975del p.G326Afs*134 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, varscan2
- CATSPERB | c.2073G>A p.M691I | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCAR2 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 14/289 reads (5%) | called by muse, mutect2
- CCDC180 | c.4903A>T p.I1635L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCR8 | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CDH10 | c.1727A>T p.Q576L | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDH10 | c.930T>G p.D310E | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDH16 | c.1358A>T p.Q453L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, varscan2
- CELSR1 | c.3662C>T p.S1221F | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPE | c.4773A>T p.E1591D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CERT1 | c.1900G>T p.V634L (on ENST00000405807 / NM_001130105.1; = p.V506L on NM_005713.3) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CES2 | c.1405T>C p.F469L | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CLSTN3 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CNTN6 | c.1104T>A p.N368K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP2 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CNTNAP2 | c.1049T>A p.L350H | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CNTNAP4 | c.2922A>T p.K974N | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL18A1 | c.4169C>T p.P1390L (on ENST00000359759 / NM_130444.3; = p.P1155L on NM_030582.4) | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- COL1A1 | c.3202G>C p.E1068Q | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- CPA4 | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPS1 | c.2683A>T p.N895Y | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CSNK1E | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CYC1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CYP4F12 | c.989A>G p.H330R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DDIT4L | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.039); called by muse, varscan2
- DGUOK | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- DHRS7C | c.421C>G p.L141V (on ENST00000330255 / NM_001220493.2; = p.L140V on NM_001105571.3) | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHRS9 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DTNA | c.1591A>G p.R531G | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DUSP10 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- E2F8 | c.1815G>C p.K605N | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ELOA2 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 68/668 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- ERVV-1 | c.616G>C p.V206L | Missense Mutation (SNP) | VAF 65/516 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EZHIP | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FAH | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- FBXO33 | c.683T>A p.V228E | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- FGFR2 | c.2336A>T p.Y779F | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- FMN2 | c.4057G>T p.A1353S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FOXN4 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- FSIP2 | c.7410G>A p.M2470I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- GABBR1 | c.1766A>T p.Q589L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GATA5 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); called by muse, mutect2
- GLCCI1 | c.696+3A>T | Splice Region (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- GPR15 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- GRIA4 | c.476A>T p.D159V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GTF2A1L | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.251); called by mutect2, varscan2
- HEPHL1 | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HERC6 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2
- HK3 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.3762G>C p.E1254D | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ICE1 | c.5105C>T p.A1702V | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- IFNL2 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IL26 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, varscan2
- INHA | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 88/537 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- INTS14 | c.1021G>A p.D341N (on ENST00000313182 / NM_001366360.2; = p.D262N on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- ITGAD | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- JAKMIP1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- JPH3 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 77/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.710T>A p.V237E | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1109 | c.2992G>C p.D998H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL1 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL6 | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 47/535 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP5-11 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 197/621 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KTI12 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMA4 | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 63/290 reads (22%) | called by muse, mutect2, varscan2
- LCMT1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- LRFN5 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K8 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 55/380 reads (14%) | called by muse, mutect2, varscan2
- MFAP3L | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MPP5 | c.1307G>T p.W436L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH2A | c.3576C>A p.H1192Q | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MUC16 | c.12503C>A p.T4168K | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MUC19 | c.17G>T p.W6L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.99); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MYBPC1 | c.905A>C p.H302P (on ENST00000550270 / NM_206820.2; = p.H327P on NM_002465.4) | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH13 | c.2229A>T p.K743N | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYH13 | c.1808T>A p.L603Q | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYH15 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALADL1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NEU2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- NOX4 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- NPTX2 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- NRIP1 | c.189T>A p.S63R | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OCLN | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 73/421 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- OR10J3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 61/303 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR13C4 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR14A2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR14C36 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR2B3 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2T33 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 30/575 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- OR52A5 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OR5H14 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6K6 | c.781C>A p.H261N (on ENST00000368144; = p.H237N on NM_001005184.1) | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR6V1 | c.777G>C p.R259S | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- PCDHB1 | c.139A>T p.N47Y | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB6 | c.530del p.F177Sfs*19 | Frame Shift Del (DEL) | VAF 21/184 reads (11%) | called by mutect2, pindel, varscan2
- PCDHGA1 | c.1514T>A p.L505H | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PCDHGA6 | c.1861C>A p.L621M | Missense Mutation (SNP) | VAF 93/482 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PCDHGB7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCLO | c.11770A>T p.T3924S | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PCLO | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 41/581 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.402); called by muse, mutect2
- PCSK5 | c.1870A>G p.T624A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2
- PDE4DIP | c.2436+2T>A p.X812_splice | Splice Site (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- PDPR | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2
- PLEC | c.11684A>G p.H3895R (on ENST00000322810 / NM_201380.4; = p.H3785R on NM_000445.5) | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PLPP7 | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPP4R3C | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- PTPRB | c.4265T>G p.L1422R | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RAB11FIP1 | c.2482G>T p.V828L | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- RALGPS2 | c.1401A>T p.K467N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RHO | c.29A>T p.Y10F | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR1 | c.4631A>G p.N1544S | Missense Mutation (SNP) | VAF 79/489 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RYR2 | c.13738A>C p.T4580P | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAGE1 | c.1822A>G p.M608V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SAMSN1 | c.236-1G>C p.X79_splice | Splice Site (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- SCN2A | c.5441A>C p.E1814A | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SERINC4 | c.262T>A p.W88R | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHANK2 | c.524T>C p.L175S | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM4 | c.1259A>T p.H420L | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- SLC29A2 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLFN14 | c.1580T>C p.L527P | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SPEN | c.378A>T p.E126D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPTBN4 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STAB2 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- STIM1 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STK32B | c.740A>T p.Y247F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); called by mutect2, varscan2
- STON1 | c.2064G>T p.R688S | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- STYXL1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.405); called by muse, mutect2
- TBXT | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- TDRD6 | c.3279G>T p.M1093I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TENT5D | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THEG | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THEGL | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM145 | c.674A>C p.Y225S | Missense Mutation (SNP) | VAF 19/331 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.347); called by muse, mutect2
- TPTE | c.1124A>C p.D375A (on ENST00000618007 / NM_199261.4; = p.D357A on NM_199259.4) | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2
- TREX2 | c.810G>C p.L270F (on ENST00000334497; = p.L227F on NM_080701.3) | Missense Mutation (SNP) | VAF 124/348 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM69 | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- TRIP12 | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- UBA3 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBP1 | c.113+1del p.X38_splice | Splice Site (DEL) | VAF 46/233 reads (20%) | called by mutect2, pindel, varscan2
- UBQLN3 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- UNC80 | c.5513C>T p.P1838L | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USE1 | c.709A>T p.M237L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- USH2A | c.5758G>T p.G1920C | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- USH2A | c.4482T>A p.N1494K | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- USH2A | c.3946G>T p.A1316S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.433); called by muse, mutect2
- VEGFC | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); called by muse, mutect2
- VGF | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- WDR49 | c.781T>C p.F261L (on ENST00000308378 / NM_001366158.1; = p.F602L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ZBBX | c.1275T>G p.S425R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.144); called by muse, mutect2
- ZEB2 | c.2828C>A p.A943E | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFR | c.2296G>C p.E766Q | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ZNF208 | c.1214G>C p.G405A | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- ZNF26 | c.1541A>T p.E514V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ZNF304 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF568 | c.925A>T p.K309* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- ZNF577 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ZNF608 | c.1801G>T p.G601* | Nonsense Mutation (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- ZNF716 | c.1031T>C p.I344T | Missense Mutation (SNP) | VAF 146/528 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF804A | c.629A>T p.H210L | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ZNF804A | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- AATK | c.3267G>C p.V1089= (on ENST00000326724 / NM_001080395.3; = p.V986= on NM_004920.2) | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1395C>A p.R465= | Silent (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- ADH1A | c.690T>C p.F230= | Silent (SNP) | VAF 34/414 reads (8%) | called by muse, mutect2
- AMZ1 | c.429C>T p.S143= | Silent (SNP) | VAF 182/517 reads (35%) | called by muse, mutect2, varscan2
- ANK2 | c.11460G>A p.R3820= | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- AOPEP | c.870C>T p.A290= | Silent (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- ATP6V0A2 | c.2283G>A p.L761= | Silent (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- ATP9A | c.1392G>C p.A464= | Silent (SNP) | VAF 59/443 reads (13%) | called by muse, mutect2, varscan2
- C1orf100 | c.18A>G p.L6= | Silent (SNP) | VAF 25/221 reads (11%) | catalogued as rs1456698592; called by muse, mutect2, varscan2
- C1orf100 | c.213C>T p.D71= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- CACNG8 | c.972G>C p.G324= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs1359350254; called by mutect2, varscan2
- CD226 | c.471G>T p.T157= | Silent (SNP) | VAF 53/256 reads (21%) | catalogued as COSV99711050; called by muse, mutect2, varscan2
- CDH8 | c.1347G>C p.T449= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- CELSR1 | c.3663C>T p.S1221= | Silent (SNP) | VAF 52/489 reads (11%) | catalogued as COSV99417230; called by muse, mutect2, varscan2
- CLASP1 | c.2496A>T p.S832= | Silent (SNP) | VAF 67/313 reads (21%) | called by muse, mutect2, varscan2
- CLPTM1L | c.477G>C p.P159= | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- CPS1 | c.6G>T p.T2= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- CPXM1 | c.552C>T p.F184= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs1477693038, COSV66046611; called by muse, mutect2
- CSMD3 | c.4611G>T p.G1537= (on ENST00000297405 / NM_001363185.1; = p.G1433= on NM_052900.3) | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- CUEDC2 | c.381G>A p.S127= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as rs546862079; called by muse, mutect2, varscan2
- CUX2 | c.382C>A p.R128= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV55623525; called by muse, mutect2, varscan2
- DTX4 | c.60T>C p.R20= | Silent (SNP) | VAF 41/252 reads (16%) | catalogued as rs747717755; called by muse, mutect2, varscan2
- ENPP2 | c.850C>A p.R284= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV50025379; called by muse, mutect2, varscan2
- EPO | c.447A>G p.P149= | Silent (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- FAAH | c.1272T>G p.P424= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- FAM155A | c.1377A>G p.*459= | Silent (SNP) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- FAN1 | c.264T>C p.D88= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- FCRLA | c.582G>A p.A194= (on ENST00000367959; = p.A171= on NM_032738.4) | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs575335846, COSV52687560, COSV52688376; called by muse, mutect2, varscan2
- GRIN2A | c.3192G>A p.T1064= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs748790515, COSV58038769, COSV58049654, COSV58059379; ClinVar: uncertain significance; called by muse, varscan2
- GRK3 | c.1314C>T p.G438= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- HCN1 | c.2460G>T p.T820= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs772076370, COSV100299478, COSV57498006; called by muse, mutect2
- HSPB3 | c.12C>T p.I4= | Silent (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2, varscan2
- HTR1B | c.333C>A p.V111= | Silent (SNP) | VAF 44/252 reads (17%) | called by muse, mutect2, varscan2
- ID1 | c.414C>A p.A138= | Silent (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- IGHE | c.1020G>A p.K340= | Silent (SNP) | VAF 34/218 reads (16%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.327G>T p.T109= | Silent (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- IL6ST | c.45C>T p.F15= | Silent (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- ITGA4 | c.2652T>C p.D884= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1321480700; called by muse, mutect2, varscan2
- KERA | c.612G>A p.L204= | Silent (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- KRT5 | c.1206T>C p.N402= | Silent (SNP) | VAF 186/528 reads (35%) | catalogued as rs770804108; called by muse, mutect2, varscan2
- LGR5 | c.21T>C p.G7= | Silent (SNP) | VAF 109/291 reads (37%) | called by muse, mutect2, varscan2
- LKAAEAR1 | c.144G>T p.P48= | Silent (SNP) | VAF 80/431 reads (19%) | called by muse, mutect2, varscan2
- LRRIQ4 | c.561C>G p.L187= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as COSV61619775; called by muse, mutect2
- MAGEL2 | c.960C>A p.A320= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- MFSD6 | c.2106C>G p.L702= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as COSV99855379; called by muse, mutect2, varscan2
- MMP9 | c.867G>A p.Q289= | Silent (SNP) | VAF 99/602 reads (16%) | called by muse, mutect2, varscan2
- MS4A12 | c.504T>C p.S168= | Silent (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- MYH4 | c.234C>T p.F78= | Silent (SNP) | VAF 48/193 reads (25%) | called by muse, mutect2, varscan2
- NLRP13 | c.2229G>T p.V743= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- NOTCH1 | c.3066C>T p.V1022= | Silent (SNP) | VAF 27/458 reads (6%) | catalogued as rs1056129279; called by muse, mutect2
- NOTUM | c.1434C>A p.A478= | Silent (SNP) | VAF 63/351 reads (18%) | called by muse, mutect2, varscan2
- OR2T27 | c.744C>A p.V248= | Silent (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- OR2W3 | c.459G>T p.V153= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as rs1558359548, COSV64457235; called by muse, mutect2, varscan2
- OR4M1 | c.621T>A p.S207= | Silent (SNP) | VAF 52/780 reads (7%) | catalogued as COSV60060934; called by muse, mutect2
- OR5A1 | c.681G>C p.A227= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs370559050, COSV57378879; called by muse, mutect2, varscan2
- PCDHB10 | c.1656G>C p.L552= | Silent (SNP) | VAF 84/598 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1857G>T p.V619= | Silent (SNP) | VAF 114/539 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.438G>T p.A146= | Silent (SNP) | VAF 34/254 reads (13%) | called by muse, mutect2, varscan2
- PIK3R6 | c.1831C>A p.R611= | Silent (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2, varscan2
- PLEC | c.2265G>A p.L755= (on ENST00000322810 / NM_201380.4; = p.L645= on NM_000445.5) | Silent (SNP) | VAF 91/557 reads (16%) | called by muse, mutect2, varscan2
- POU5F1B | c.570G>T p.L190= | Silent (SNP) | VAF 103/465 reads (22%) | called by muse, varscan2
- PPDPF | c.213G>A p.V71= | Silent (SNP) | VAF 75/444 reads (17%) | called by muse, mutect2, varscan2
- PRDM9 | c.1275C>A p.L425= | Silent (SNP) | VAF 64/458 reads (14%) | catalogued as COSV57011959; called by muse, varscan2
- PRELP | c.183C>A p.P61= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV58115343; called by muse, mutect2, varscan2
- PRKG2 | c.1842A>T p.P614= | Silent (SNP) | VAF 29/326 reads (9%) | called by muse, mutect2
- PRR12 | c.615G>T p.P205= (on ENST00000615927; = p.P1026= on NM_020719.3) | Silent (SNP) | VAF 90/387 reads (23%) | catalogued as rs1359429732; called by muse, mutect2, varscan2
- RBM34 | c.483A>T p.T161= | Silent (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
- RITA1 | c.654C>T p.P218= | Silent (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.327G>T p.T109= | Silent (SNP) | VAF 29/218 reads (13%) | catalogued as rs753300024; called by muse, mutect2, varscan2
- SEZ6L | c.2274T>C p.T758= | Silent (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- SLC16A5 | c.258G>T p.G86= | Silent (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- SLC28A1 | c.915C>A p.A305= | Silent (SNP) | VAF 99/503 reads (20%) | called by muse, mutect2, varscan2
- SLC7A14 | c.591C>T p.V197= | Silent (SNP) | VAF 34/281 reads (12%) | called by muse, mutect2, varscan2
- TDRD6 | c.12G>A p.T4= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs1018302482, COSV60175608; called by muse, mutect2, varscan2
- TMPRSS11E | c.456C>A p.P152= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV59517895; called by muse, mutect2, varscan2
- TPSAB1 | c.729C>T p.S243= | Silent (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- TRAF5 | c.732A>T p.S244= | Silent (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- TRIM48 | c.375C>T p.S125= | Silent (SNP) | VAF 72/502 reads (14%) | catalogued as rs1475429327, COSV101338374; called by muse, mutect2, varscan2
- TTN | c.76074T>C p.Y25358= (on ENST00000591111; = p.Y17934= on NM_003319.4) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs753036492, COSV60300442; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.61740C>A p.G20580= (on ENST00000591111; = p.G13156= on NM_003319.4) | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- UCK2 | c.81G>T p.G27= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- UTP14A | c.330C>G p.V110= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- VWA5B1 | c.3558G>A p.T1186= (on ENST00000375079; = p.T1181= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/286 reads (23%) | catalogued as rs371978257; called by muse, mutect2, varscan2
- ZBTB5 | c.1944G>A p.K648= | Silent (SNP) | VAF 13/345 reads (4%) | called by muse, mutect2
- ZFHX4 | c.9150G>A p.L3050= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs1031068919; called by muse, varscan2
- ZNF208 | c.768C>A p.S256= | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- ZNF335 | c.720G>A p.V240= | Silent (SNP) | VAF 47/335 reads (14%) | called by muse, mutect2, varscan2
- ZNF358 | c.1446C>A p.S482= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs758071669, COSV99900925; called by muse, mutect2
- ZNF729 | c.2892C>T p.Y964= | Silent (SNP) | VAF 35/218 reads (16%) | catalogued as rs765038767; called by muse, mutect2, varscan2
- ZNF80 | c.465C>T p.H155= | Silent (SNP) | VAF 47/387 reads (12%) | called by muse, mutect2, varscan2
- ZNF804B | c.3561T>A p.T1187= | Silent (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- ABCC5 | c.591+63C>G | Intron (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- AC235097.1 | n.85G>T | RNA (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- CCDC110 | chr4:185472162 G>A | 5'Flank (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- CCNDBP1 | c.-51C>T | 5'UTR (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- CELF4 | c.1333+37C>A | Intron (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- DNM2 | c.1558-538A>T | Intron (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2, varscan2
- EI24P4 | n.860C>G | RNA (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- EP400P1 | n.726G>C | RNA (SNP) | VAF 89/527 reads (17%) | called by muse, mutect2, varscan2
- GALC | c.195+564G>A | Intron (SNP) | VAF 38/419 reads (9%) | called by muse, mutect2
- GTF2IRD2P1 | chr7:73269279 C>A | 5'Flank (SNP) | VAF 38/773 reads (5%) | called by muse, mutect2
- HCG27 | n.123+280G>A | Intron (SNP) | VAF 7/74 reads (9%) | catalogued as rs1389016736; called by muse, mutect2
- HLA-DRB9 | n.275C>T | RNA (SNP) | VAF 45/229 reads (20%) | called by muse, mutect2, varscan2
- KANK1 | c.3996+69A>G | Intron (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- KCNMA1 | c.3016+793A>G | Intron (SNP) | VAF 27/104 reads (26%) | catalogued as rs1564871673; called by muse, mutect2, varscan2
- KIAA1109 | c.10540-234C>G | Intron (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- KIF7 | c.329-97A>G | Intron (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- LINC02272 | n.268G>T | RNA (SNP) | VAF 11/89 reads (12%) | catalogued as rs776178770; called by muse, mutect2, varscan2
- MAP2K1 | c.1068+43A>C | Intron (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2, varscan2
- MERTK | c.*28A>G | 3'UTR (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- MGP | c.95-33C>T | Intron (SNP) | VAF 43/161 reads (27%) | called by muse, mutect2, varscan2
- MOSPD2 | c.-10G>A | 5'UTR (SNP) | VAF 14/106 reads (13%) | catalogued as COSV100146696; called by muse, mutect2
- NRK | c.-45G>A | 5'UTR (SNP) | VAF 54/161 reads (34%) | called by muse, mutect2, varscan2
- OSMR | c.1585+164T>C | Intron (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-418C>A | Intron (SNP) | VAF 90/489 reads (18%) | called by muse, mutect2, varscan2
- PDIA3P1 | n.1885G>C | RNA (SNP) | VAF 10/257 reads (4%) | called by muse, mutect2
- PLP1 | c.-36C>A | 5'UTR (SNP) | VAF 50/140 reads (36%) | catalogued as rs1364374999; called by muse, mutect2, varscan2
- PRMT1 | c.91-263G>C | Intron (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- RNF43 | c.2308+265G>T | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2
- SATB2 | c.347-15952G>A | Intron (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- SH2B2 | chr7:102280824 G>A | 5'Flank (SNP) | VAF 26/252 reads (10%) | catalogued as COSV99475251; called by muse, mutect2, varscan2
- SHLD2P3 | n.2456A>T | RNA (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- SPATA31C1 | n.1048C>A | RNA (SNP) | VAF 34/458 reads (7%) | called by muse, mutect2
- TRAPPC12 | c.1047+1102A>G | Intron (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- TRBV21OR9-2 | n.343A>G | RNA (SNP) | VAF 9/36 reads (25%) | catalogued as rs1467243943; called by muse, mutect2, varscan2
- VAMP8 | c.162+648G>A | Intron (SNP) | VAF 24/173 reads (14%) | catalogued as rs749268313; called by muse, mutect2, varscan2
- VAPB | c.*217G>T | 3'UTR (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- VAPB | c.*1702G>T | 3'UTR (SNP) | VAF 57/305 reads (19%) | called by muse, mutect2, varscan2
- WDR55 | c.*2147C>T | 3'UTR (SNP) | VAF 37/174 reads (21%) | called by muse, mutect2, varscan2
- ZNF827 | c.3230+84G>T | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- ZNF91 | c.-31G>C | 5'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
